Somatic mutation profile of tumor specimen TCGA-64-1679-01A (aliquot TCGA-64-1679-01A-21D-2063-08) from TCGA case TCGA-64-1679, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 58.3 years (21,310 days).
Specimen TCGA-64-1679-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6eb5d46b-ab8b-47f0-a36e-e73f9e05542e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-64-1679-10A (Blood Derived Normal), aliquot TCGA-64-1679-10A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c4c42d3-93a5-4222-9d7f-baee2ccb9694

The open-access MAF lists 545 somatic variants for this specimen: 422 protein-altering or splice-affecting, 111 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 358, Silent 111, Nonsense Mutation 31, Splice Site 15, Frame Shift Del 9, Intron 5, Frame Shift Ins 5, 3'UTR 3, 3'Flank 2, Splice Region 1, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.1113G>T p.E371D | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV52227260, COSV99287671; called by muse, mutect2, varscan2
- ABCA4 | c.5846G>T p.G1949V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.813); catalogued as COSV64676159; called by muse, mutect2, varscan2
- ABCG8 | c.657G>T p.R219S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV55393435, COSV55397964; called by muse, mutect2
- ABCG8 | c.1746C>G p.S582R | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV55395372; called by muse, mutect2, varscan2
- ABL2 | c.1712G>T p.R571L (on ENST00000502732 / NM_007314.4; = p.R556L on NM_005158.5) | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV61013590, COSV61018775; called by muse, mutect2, varscan2
- ADAMTS12 | c.2267G>C p.G756A | Missense Mutation (SNP) | VAF 34/293 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV61263232, COSV61272776; called by muse, mutect2, varscan2
- ADAMTS13 | c.2609A>T p.H870L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1403157372, COSV63022512; called by muse, mutect2, varscan2
- ADAMTS16 | c.2034A>C p.L678F | Missense Mutation (SNP) | VAF 71/150 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV57001063; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2777C>A p.P926H | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54460692; called by muse, mutect2, varscan2
- ADGRB1 | c.1929G>C p.Q643H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.995); catalogued as COSV60101641; called by muse, mutect2, varscan2
- ADGRE2 | c.859G>T p.D287Y | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV59695408; called by muse, mutect2
- ADGRE2 | c.388T>C p.C130R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV59695413; called by muse, mutect2, varscan2
- ADGRE5 | c.379T>C p.C127R | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54413629; called by muse, mutect2
- ADGRL3 | c.897T>G p.F299L (on ENST00000506720 / NM_001322402.2; = p.F231L on NM_015236.6) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV72270450; called by muse, mutect2, varscan2
- AHNAK | c.2618G>T p.W873L | Missense Mutation (SNP) | VAF 130/422 reads (31%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.852); catalogued as COSV57224295; called by muse, mutect2, varscan2
- AKR1B15 | c.716G>T p.S239I | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV71152541; called by muse, mutect2, varscan2
- ANKRD55 | c.1458C>A p.C486* | Nonsense Mutation (SNP) | VAF 54/197 reads (27%) | catalogued as COSV61949181; called by muse, mutect2, varscan2
- APOA5 | c.550A>C p.T184P | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV57064253; called by muse, mutect2, varscan2
- AQR | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV50035232; called by muse, mutect2, varscan2
- ARHGEF40 | c.2590G>T p.V864F | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.249); catalogued as COSV53882885; called by muse, mutect2, varscan2
- ARHGEF5 | c.62G>T p.S21I | Missense Mutation (SNP) | VAF 22/376 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.143); catalogued as COSV50215190; called by muse, mutect2
- ASPHD2 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.122); catalogued as COSV53220121; called by muse, mutect2
- ATAD2 | c.584G>T p.R195L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54883572, COSV54884865; called by muse, mutect2
- BACH2 | c.1134G>T p.Q378H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100000048; called by muse, mutect2
- BAZ1A | c.2882C>A p.S961Y | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as COSV62411598; called by muse, mutect2, varscan2
- BAZ2B | c.901-1G>T p.X301_splice | Splice Site (SNP) | VAF 32/164 reads (20%) | catalogued as COSV58606898; called by muse, mutect2, varscan2
- BLK | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs761710037, COSV52054682; called by muse, mutect2, varscan2
- BMT2 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.727); catalogued as COSV51779675; called by muse, mutect2, varscan2
- BPI | c.39del p.R14Dfs*5 (on ENST00000262865; = p.R10Dfs*5 on NM_001725.3) | Frame Shift Del (DEL) | VAF 15/124 reads (12%) | catalogued as COSV53405146; called by mutect2, varscan2
- BPI | c.815C>A p.P272Q (on ENST00000262865; = p.P268Q on NM_001725.3) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53407353; called by muse, mutect2, varscan2
- BPIFB4 | c.1753G>T p.G585C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64951893; called by muse, mutect2, varscan2
- BRINP1 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV56308709; called by muse, mutect2, varscan2
- BST1 | c.254T>A p.V85E | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV53947971; called by muse, mutect2, varscan2
- BTBD7 | c.2203G>T p.V735L | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.038); catalogued as rs190609675, COSV58289217; called by muse, mutect2, varscan2
- C12orf66 | c.800C>G p.A267G | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV61324200, COSV61324230; called by muse, mutect2, varscan2
- C7 | c.1931C>A p.P644H | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57474608, COSV57478255; called by muse, mutect2
- C9orf43 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55913556; called by muse, mutect2, varscan2
- CACNA2D1 | c.2305G>T p.D769Y (on ENST00000356253 / NM_001366867.1; = p.D757Y on NM_000722.4) | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.385); catalogued as COSV62375605; called by muse, mutect2, varscan2
- CACNG3 | c.437-2A>T p.X146_splice | Splice Site (SNP) | VAF 29/174 reads (17%) | catalogued as COSV50077717; called by muse, mutect2, varscan2
- CADPS | c.1162C>A p.Q388K | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0.014); catalogued as COSV51894471; called by muse, mutect2, varscan2
- CAPN15 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV54838554; called by muse, mutect2, varscan2
- CASQ1 | c.350T>A p.V117E | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63624420; called by muse, mutect2, varscan2
- CCR8 | c.29C>A p.T10K | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV58337731; called by muse, mutect2, varscan2
- CD109 | c.4141A>G p.I1381V | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs776327565, COSV54654193; called by muse, mutect2, varscan2
- CD5L | c.51C>A p.F17L | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63821019, COSV63822774; called by muse, mutect2, varscan2
- CDHR2 | c.1042G>T p.D348Y | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56142891; called by muse, mutect2, varscan2
- CDK12 | c.980A>G p.Y327C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as rs376614675, COSV71002143; called by muse, mutect2, varscan2
- CDKL5 | c.2126C>A p.P709Q | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV66112591; called by muse, mutect2, varscan2
- CENPF | c.5695G>C p.D1899H | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV65277538; called by muse, mutect2, varscan2
- CEP192 | c.2174C>T p.A725V | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.168); catalogued as COSV58068405; called by muse, mutect2
- CEP57L1 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs764390366, COSV61245816; called by muse, mutect2, varscan2
- CFHR1 | c.941G>T p.R314L | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV57625702, COSV57628365; called by muse, mutect2, varscan2
- CGNL1 | c.1369G>T p.A457S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.05); catalogued as rs776934188, COSV55572611; called by muse, mutect2, varscan2
- CIITA | c.797T>C p.V266A | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60860433; called by muse, mutect2
- CLCN1 | c.1392C>A p.F464L | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.216); catalogued as COSV58372895; called by muse, mutect2, varscan2
- CLDND1 | c.342G>T p.Q114H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57859698; called by muse, mutect2, varscan2
- CMTR2 | c.464A>T p.N155I | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57604507; called by muse, mutect2, varscan2
- CMYA5 | c.5688G>T p.L1896F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV101484242; called by muse, mutect2
- CNPY1 | c.278A>G p.*93Wext*11 | Nonstop Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV58788071, COSV58788169; called by muse, mutect2, varscan2
- CNST | c.1892G>C p.G631A | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV63624035; called by muse, mutect2, varscan2
- CNTNAP2 | c.478C>A p.R160S | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62208430, COSV62223787; called by muse, mutect2, varscan2
- CNTNAP4 | c.1882G>T p.E628* | Nonsense Mutation (SNP) | VAF 21/85 reads (25%) | catalogued as COSV56686972, COSV56693705; called by muse, mutect2
- CNTNAP5 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV70501811; called by muse, mutect2, varscan2
- COLGALT2 | c.864C>A p.H288Q | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.296); catalogued as COSV62300176; called by muse, mutect2, varscan2
- CPED1 | c.2843G>A p.G948E | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59997999; called by muse, mutect2, varscan2
- CPED1 | c.3067A>G p.K1023E | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV60001202; called by muse, varscan2
- CREM | c.34G>T p.G12* | Nonsense Mutation (SNP) | VAF 10/103 reads (10%) | catalogued as COSV100415367; called by muse, mutect2, varscan2
- CTTNBP2NL | c.340G>T p.D114Y | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54746080, COSV99600278; called by muse, mutect2
- CUL3 | c.208G>C p.G70R | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52368270; called by muse, mutect2
- CYP4F2 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as rs1388353329, COSV55620300; called by muse, varscan2
- CYTL1 | c.205T>A p.C69S | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57037546; called by muse, mutect2, varscan2
- DBT | c.1259T>A p.I420N | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64496025; called by muse, mutect2, varscan2
- DCAF8L1 | c.615C>A p.N205K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV71595439; called by muse, mutect2, varscan2
- DGKB | c.352C>A p.P118T | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as rs1245145705, COSV51807033; called by muse, mutect2, varscan2
- DLGAP2 | c.2287C>T p.R763* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as COSV70100457; called by muse, mutect2
- DMBX1 | c.776C>A p.S259Y | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as rs777100537, COSV63601696, COSV63602417; called by muse, mutect2, varscan2
- DMKN | c.557T>G p.M186R | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV60088266; called by muse, mutect2, varscan2
- DNAH5 | c.6648G>T p.K2216N | Missense Mutation (SNP) | VAF 135/266 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV54242618; called by muse, mutect2, varscan2
- DNAJC12 | c.289G>T p.V97L | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV56549189; called by muse, mutect2, varscan2
- DNAJC21 | c.464G>T p.W155L | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV57761851; called by muse, mutect2
- DNAJC8 | c.20G>T p.S7I | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.059); catalogued as COSV55282247, COSV55282606; called by muse, mutect2, varscan2
- DOCK3 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as COSV56539443; called by muse, mutect2, varscan2
- DOCK8 | c.895-1G>C p.X299_splice | Splice Site (SNP) | VAF 22/74 reads (30%) | catalogued as COSV66635088; called by muse, mutect2, varscan2
- DRC1 | c.1761G>T p.E587D | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV55512887; called by muse, mutect2, varscan2
- DRC7 | c.1885G>T p.A629S | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.203); catalogued as COSV61056967; called by muse, mutect2, varscan2
- DRD5 | c.1090G>T p.D364Y | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58579597, COSV58580082; called by muse, mutect2, varscan2
- DTNA | c.2147G>T p.R716L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.586); catalogued as COSV52017967; called by muse, mutect2, varscan2
- ECHS1 | c.148A>T p.I50F | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV63907175; called by muse, mutect2, varscan2
- ECT2L | c.997C>A p.L333M | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62886231; called by muse, mutect2, varscan2
- EFCAB14 | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200133048; called by muse, mutect2, varscan2
- ELAVL4 | c.119C>A p.T40N | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV63918266; called by muse, mutect2, varscan2
- ELOVL6 | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56431197; called by muse, mutect2, varscan2
- EP400 | c.1565A>T p.Q522L | Missense Mutation (SNP) | VAF 36/239 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); catalogued as COSV57781365; called by muse, mutect2, varscan2
- EPHA5 | c.2531G>T p.W844L | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56662087, COSV56674027, COSV56679757; called by muse, mutect2
- EPHA5 | c.698G>C p.C233S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56662100; called by muse, mutect2, varscan2
- EPHB1 | c.2737T>A p.F913I | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.229); catalogued as COSV67667518; called by muse, mutect2, varscan2
- ERICH3 | c.2488G>T p.E830* | Nonsense Mutation (SNP) | VAF 24/111 reads (22%) | catalogued as COSV58603692, COSV58614001; called by muse, mutect2, varscan2
- EYA4 | c.511G>T p.G171W | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as CM154547, COSV62058091; called by muse, mutect2, varscan2
- F13B | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.404); catalogued as rs915458369, COSV66372951; called by muse, mutect2
- F5 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746260106, COSV63123083; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM83D | c.610G>T p.D204Y | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54158361; called by muse, mutect2, varscan2
- FAM83D | c.776+2T>A p.X259_splice | Splice Site (SNP) | VAF 17/77 reads (22%) | catalogued as COSV54158369; called by muse, mutect2, varscan2
- FCHO1 | c.1635G>T p.M545I | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV53184181; called by muse, mutect2
- FCRL5 | c.1841C>A p.S614Y | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.815); catalogued as COSV62518184; called by muse, mutect2, varscan2
- FLG | c.9654C>G p.D3218E | Missense Mutation (SNP) | VAF 69/396 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV64245734, COSV64249077; called by muse, mutect2, varscan2
- FLG2 | c.4297C>A p.H1433N | Missense Mutation (SNP) | VAF 75/442 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV66169121, COSV66171356; called by muse, mutect2, varscan2
- FMN2 | c.1216C>G p.R406G | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.518); catalogued as COSV60444569; called by mutect2, varscan2
- FNDC1 | c.3902G>C p.R1301T | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1207455696, COSV51937012, COSV51944534; called by muse, mutect2, varscan2
- FOXN4 | c.637A>T p.S213C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as COSV54496825; called by muse, varscan2
- FPGT | c.1715A>G p.Y572C | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs372383046, COSV63836227; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1717C>A p.Q573K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); catalogued as COSV58561736; called by muse, mutect2, varscan2
- FREM2 | c.5542G>A p.E1848K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758038374, COSV54846372; called by muse, mutect2, varscan2
- GABRG1 | c.1003C>A p.L335I | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54959110; called by muse, mutect2, varscan2
- GABRQ | c.891G>T p.R297S | Missense Mutation (SNP) | VAF 84/362 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64783381; called by muse, mutect2, varscan2
- GAD2 | c.1388G>A p.G463E | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52164145; called by muse, mutect2
- GATA6 | c.1585A>C p.N529H | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.783); catalogued as COSV52527012; called by muse, mutect2, varscan2
- GCM2 | c.1279C>A p.P427T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as COSV65275294, COSV65276257; called by muse, mutect2, varscan2
- GFRA1 | c.704A>G p.Y235C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV62609040; called by muse, mutect2, varscan2
- GGA3 | c.1558G>T p.D520Y (on ENST00000537686 / NM_138619.4; = p.D487Y on NM_014001.5) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV55458158, COSV99822343; called by muse, mutect2, varscan2
- GLRA4 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as COSV65456591, COSV65457201; called by muse, mutect2, varscan2
- GLYAT | c.112G>T p.G38* | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as rs746093728, COSV53539976, COSV53540147; called by muse, mutect2, varscan2
- GPCPD1 | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as COSV66831453; called by muse, mutect2, varscan2
- GPR148 | c.673C>G p.L225V | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.163); catalogued as COSV59309032, COSV99998455; called by muse, mutect2, varscan2
- GPR32 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.158); catalogued as COSV54515197; called by muse, mutect2, varscan2
- GRM3 | c.1589T>A p.I530N | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.964); catalogued as COSV64475841, COSV64477073; called by muse, mutect2
- GTF2IRD1 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 7/56 reads (13%) | catalogued as COSV56089882, COSV56092849; called by muse, mutect2, varscan2
- GUCY2F | c.1657C>A p.L553I | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV54306384; called by muse, mutect2, varscan2
- H2BC12 | c.71A>T p.K24M | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV63617472; called by muse, mutect2, varscan2
- H2BC13 | c.260G>C p.R87P | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV100704342, COSV62441068; called by muse, mutect2, varscan2
- H3-5 | c.323A>T p.N108I | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV61187268, COSV61187918; called by muse, mutect2, varscan2
- HAP1 | c.1777G>A p.E593K (on ENST00000310778 / NM_001367460.1; = p.E541K on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV57879964; called by muse, mutect2
- HAVCR2 | c.343C>G p.P115A | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as COSV57154241; called by muse, mutect2
- HBD | c.48G>T p.W16C | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV53083304; called by muse, mutect2, varscan2
- HLA-DQB1 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 22/93 reads (24%) | catalogued as COSV66571634, COSV66573558; called by muse, varscan2
- HOXC10 | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV100329132; called by muse, mutect2, varscan2
- IFI44 | c.640G>T p.V214L | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.437); catalogued as COSV66075332; called by muse, mutect2, varscan2
- IGSF21 | c.315G>T p.E105D | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99245753; called by muse, mutect2, varscan2
- INTS4 | c.1249G>C p.V417L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV71090737; called by muse, mutect2
- INTS6L | c.2222G>T p.G741V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV66085487; called by muse, mutect2, varscan2
- ISLR2 | c.2073G>C p.Q691H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV62303056; called by muse, mutect2
- ISY1-RAB43 | c.596G>A p.R199K | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs910968961, COSV56442456; called by muse, mutect2, varscan2
- ITGA2B | c.1790T>A p.V597E | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as COSV52234147; called by muse, mutect2, varscan2
- ITGAE | c.2225G>T p.C742F | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as COSV53997712; called by muse, mutect2, varscan2
- ITPR3 | c.5113G>T p.D1705Y | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV65407460, COSV65413142; called by muse, mutect2, varscan2
- JAKMIP2 | c.891A>T p.K297N | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV54611473; called by muse, mutect2, varscan2
- JUP | c.191G>C p.G64A | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV60279174; called by muse, mutect2, varscan2
- KBTBD2 | c.1775A>T p.E592V | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as COSV58364037; called by muse, mutect2, varscan2
- KBTBD8 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 25/133 reads (19%) | catalogued as COSV55130530; called by muse, mutect2, varscan2
- KCNE4 | c.550G>C p.D184H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56055061; called by muse, mutect2, varscan2
- KCNF1 | c.493C>A p.Q165K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.424); catalogued as COSV99705809; called by muse, mutect2, varscan2
- KCNF1 | c.494A>G p.Q165R | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.07); catalogued as COSV99705813; called by muse, mutect2, varscan2
- KCNJ5 | c.424T>G p.F142V | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57969178; called by muse, mutect2, varscan2
- KCNN2 | c.1621G>T p.E541* (on ENST00000264773; = p.E753* on NM_021614.4) | Nonsense Mutation (SNP) | VAF 39/119 reads (33%) | catalogued as COSV53295572; called by muse, mutect2, varscan2
- KIF13A | c.3559G>T p.A1187S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV52460739; called by muse, mutect2, varscan2
- KIF25 | c.914C>A p.A305D | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63027722, COSV63028299; called by muse, mutect2, varscan2
- KMO | c.1064C>A p.A355E | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59364691, COSV59366341, COSV59366427; called by muse, mutect2, varscan2
- KMT2D | c.7802C>T p.T2601I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV56470690; called by muse, mutect2, varscan2
- KRBOX4 | c.34G>C p.D12H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV53343959, COSV99994173; called by muse, mutect2, varscan2
- KRT37 | c.1246C>A p.P416T | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.538); catalogued as COSV56659308; called by muse, mutect2, varscan2
- KRT6B | c.857C>G p.A286G | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.174); catalogued as COSV52885484; called by muse, varscan2
- KRTAP3-3 | c.166C>A p.H56N | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.621); catalogued as COSV66956748; called by muse, mutect2, varscan2
- KRTAP9-3 | c.140G>C p.C47S | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.02); catalogued as COSV100893216, COSV66647161; called by muse, mutect2, varscan2
- KYNU | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV51588759; called by muse, mutect2, varscan2
- LAMA1 | c.928C>G p.Q310E | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV101057124, COSV67541525; called by muse, mutect2, varscan2
- LAMA5 | c.7867+1G>T p.X2623_splice | Splice Site (SNP) | VAF 6/14 reads (43%) | catalogued as COSV53367639; called by muse, mutect2, varscan2
- LAMB1 | c.5186T>A p.L1729H | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52739088; called by muse, mutect2, varscan2
- LAMB1 | c.595C>G p.P199A | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55968457; called by muse, mutect2, varscan2
- LARP1 | c.1416G>C p.E472D (on ENST00000518297 / NM_033551.3; = p.E395D on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV60429985; called by muse, mutect2
- LAT | c.9G>T p.E3D | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.047); catalogued as COSV57955968; called by muse, mutect2
- LCE3D | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.021); catalogued as COSV64231054; called by muse, mutect2, varscan2
- LCT | c.2344G>T p.V782L | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.834); catalogued as rs1285454309, COSV51554701; called by muse, mutect2
- LDB2 | c.610C>A p.L204I | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58777070; called by muse, mutect2, varscan2
- LETM1 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.432); catalogued as rs539912035, COSV57103238; called by muse, mutect2, varscan2
- LILRA6 | c.942C>G p.N314K | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV54445996; called by muse, mutect2
- LMO4 | c.270C>A p.C90* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV65170492; called by muse, mutect2, varscan2
- LPA | c.4862G>T p.G1621V | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60307195; called by muse, mutect2, varscan2
- LRFN5 | c.137C>A p.P46Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53269088; called by muse, mutect2, varscan2
- LRP2 | c.13328C>T p.A4443V | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1421381409, COSV55566531; called by muse, mutect2, varscan2
- LTBP1 | c.3691C>A p.Q1231K (on ENST00000404816 / NM_206943.4; = p.Q905K on NM_000627.4) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.403); catalogued as COSV55383230; called by muse, mutect2, varscan2
- LY6G5B | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV65508103; called by muse, mutect2, varscan2
- MAGEA10 | c.254A>T p.Q85L | Missense Mutation (SNP) | VAF 53/235 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV54885160; called by muse, mutect2, varscan2
- MAGEA12 | c.740C>T p.T247I | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV100756999; called by muse, mutect2, varscan2
- MAP3K19 | c.1215C>A p.S405R | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV59640540, COSV59641062; called by muse, mutect2, varscan2
- MAP4K2 | c.1365+1G>A p.X455_splice | Splice Site (SNP) | VAF 14/47 reads (30%) | catalogued as COSV53646650; called by muse, mutect2, varscan2
- MARCO | c.716C>G p.P239R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV59056882; called by muse, mutect2, varscan2
- MASP1 | c.405C>A p.Y135* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as COSV51462456; called by muse, mutect2, varscan2
- MFSD1 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs769958466, COSV51842440; called by muse, mutect2, varscan2
- MIGA1 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV66224482; called by muse, mutect2, varscan2
- MIOX | c.52G>T p.D18Y | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV53314140; called by muse, mutect2, varscan2
- MIPOL1 | c.494-1G>T p.X165_splice | Splice Site (SNP) | VAF 33/138 reads (24%) | catalogued as COSV59389898; called by muse, mutect2, varscan2
- MRAP2 | c.23C>A p.S8Y | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV100004925, COSV57631745; called by muse, mutect2, varscan2
- MROH7 | c.2716G>C p.V906L | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.146); catalogued as COSV59875743; called by muse, mutect2, varscan2
- MSL2 | c.1354G>T p.V452L | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.133); catalogued as rs762498849, COSV53868407; called by muse, mutect2, varscan2
- MYH2 | c.3021G>T p.E1007D | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV55444690; called by muse, mutect2, varscan2
- MYH3 | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV56868267; called by muse, mutect2, varscan2
- NAGPA | c.844G>T p.A282S | Missense Mutation (SNP) | VAF 24/150 reads (16%) | PolyPhen probably damaging (1); catalogued as COSV100392986, COSV56570546; called by muse, mutect2, varscan2
- NALCN | c.888G>T p.W296C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51932690, COSV99216766; called by muse, mutect2, varscan2
- NALCN | c.887G>T p.W296L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV99216772; called by muse, mutect2, varscan2
- NCAM2 | c.899-1G>A p.X300_splice | Splice Site (SNP) | VAF 12/52 reads (23%) | catalogued as COSV53093533; called by muse, varscan2
- NCKAP1 | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62942621; called by muse, mutect2, varscan2
- NDC1 | c.1713A>T p.L571F | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52337573; called by muse, mutect2, varscan2
- NEDD4 | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.617); catalogued as rs760080515, COSV59064878; called by muse, mutect2
- NELFCD | c.328C>G p.L110V (on ENST00000602795; = p.L92V on NM_198976.4) | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59748191; called by muse, mutect2, varscan2
- NF1 | c.1186-2A>G p.X396_splice | Splice Site (SNP) | VAF 60/144 reads (42%) | catalogued as CS086403, COSV62213815; called by muse, mutect2, varscan2
- NFU1 | c.315G>T p.R105S (on ENST00000410022 / NM_001002755.4; = p.R81S on NM_015700.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.3); catalogued as COSV100361291; called by muse, mutect2, varscan2
- NKTR | c.2000G>A p.R667K | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.388); catalogued as rs757874199, COSV51774016; called by muse, mutect2, varscan2
- NLRP11 | c.2108T>A p.L703Q | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV64088375; called by muse, mutect2, varscan2
- NLRP14 | c.2158G>A p.D720N | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as COSV55070328; called by muse, mutect2, varscan2
- NLRP5 | c.3283G>C p.V1095L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV66766486; called by muse, mutect2, varscan2
- NLRP7 | c.1909G>T p.E637* | Nonsense Mutation (SNP) | VAF 24/67 reads (36%) | catalogued as COSV60178997; called by muse, mutect2, varscan2
- NMS | c.404T>G p.F135C | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as COSV65259090; called by muse, mutect2, varscan2
- NOL8 | c.2820A>C p.K940N | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV62636759; called by muse, mutect2, varscan2
- NOS1 | c.3728G>T p.R1243L | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs765858548, COSV57606663, COSV57623097; called by muse, mutect2, varscan2
- NPAS3 | c.323A>C p.N108T (on ENST00000356141 / NM_001164749.2; = p.N78T on NM_022123.3) | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as rs776658678, COSV58100948; called by muse, mutect2, varscan2
- NR1D2 | c.471G>C p.Q157H | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56993163; called by muse, mutect2, varscan2
- NTF3 | c.100C>A p.L34I | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as COSV58418122; called by muse, mutect2, varscan2
- NTRK3 | c.604A>T p.M202L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58135505; called by muse, mutect2
- NXPE3 | c.1621G>T p.V541F | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.219); catalogued as COSV56291457; called by muse, mutect2, varscan2
- OCA2 | c.2254C>A p.L752I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.088); catalogued as COSV62353537; called by muse, mutect2, varscan2
- OLFML3 | c.1016C>A p.P339H | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.888); catalogued as COSV100233176; called by muse, mutect2
- OR10G8 | c.351G>T p.M117I | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV70909055; called by muse, mutect2, varscan2
- OR10K2 | c.308C>A p.S103Y | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV59222191, COSV59222680; called by muse, mutect2, varscan2
- OR10V1 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV55700023; called by muse, mutect2, varscan2
- OR11G2 | c.97A>T p.R33W | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV62132843; called by muse, mutect2, varscan2
- OR1N2 | c.82C>G p.P28A | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.043); catalogued as rs1385558169, COSV65460997; called by muse, mutect2, varscan2
- OR2H1 | c.170T>C p.M57T | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV65811155; called by muse, mutect2, varscan2
- OR4A15 | c.378G>T p.K126N | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.963); catalogued as COSV59036687; called by muse, mutect2, varscan2
- OR51E2 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV67808336; called by muse, mutect2, varscan2
- OR7A10 | c.386C>A p.P129H | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs373353751, COSV50166640; called by muse, varscan2
- OSBP2 | c.559G>T p.G187C | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60246502; called by muse, mutect2, varscan2
- OTOA | c.450G>T p.L150F | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.1); catalogued as COSV53760779; called by muse, mutect2, varscan2
- OTOF | c.4298G>T p.R1433L (on ENST00000272371 / NM_194248.3; = p.R666L on NM_004802.4) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55512906, COSV99718518; called by muse, mutect2, varscan2
- OTOF | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as COSV55512938; called by muse, mutect2, varscan2
- OTOGL | c.2033G>T p.C678F (on ENST00000547103; = p.C669F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101509462; called by muse, mutect2, varscan2
- OTOL1 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.096); catalogued as COSV100019938, COSV100020150; called by muse, mutect2, varscan2
- PABPC5 | c.575C>A p.T192N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV57042407; called by muse, mutect2, varscan2
- PADI3 | c.74C>A p.T25N | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.997); catalogued as rs767598417, COSV64935016; called by muse, mutect2, varscan2
- PANX3 | c.411C>A p.S137R | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.494); catalogued as COSV52513358; called by muse, mutect2, varscan2
- PATJ | c.5379-1G>T p.X1793_splice | Splice Site (SNP) | VAF 5/73 reads (7%) | catalogued as COSV100957503; called by muse, mutect2
- PCDH11X | c.3547C>A p.Q1183K | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV53491620; called by muse, mutect2, varscan2
- PCDHB10 | c.18G>T p.L6F | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV53382015; called by muse, mutect2, varscan2
- PCDHB11 | c.1609G>A p.G537S | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV61313090, COSV61314400; called by muse, mutect2, varscan2
- PCDHB14 | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.141); catalogued as rs572749343, COSV53390186; called by muse, mutect2, varscan2
- PCDHB6 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.028); catalogued as COSV50689835; called by muse, mutect2, varscan2
- PCDHGA1 | c.2179G>T p.A727S | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as COSV65298393; called by muse, mutect2, varscan2
- PCDHGA8 | c.2047G>T p.D683Y | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.077); catalogued as COSV54001526; called by muse, mutect2, varscan2
- PCSK2 | c.1638G>T p.K546N | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV52728496, COSV52732788; called by muse, mutect2, varscan2
- PDE3A | c.2889G>T p.Q963H | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs759014187, COSV100762633; called by muse, mutect2
- PDGFRA | c.2860C>A p.L954M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57271615; called by muse, mutect2, varscan2
- PER3 | c.2398C>T p.P800S | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as COSV62707172; called by muse, mutect2, varscan2
- PGBD4 | c.1736A>T p.Y579F | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV56628663; called by muse, mutect2, varscan2
- PGBD5 | c.262G>T p.G88* (on ENST00000525115; = p.G157* on NM_001258311.2) | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as COSV58412943; called by muse, mutect2, varscan2
- PGP | c.703A>T p.K235* | Nonsense Mutation (SNP) | VAF 15/112 reads (13%) | catalogued as COSV57030679; called by muse, mutect2, varscan2
- PHF20 | c.2134G>T p.D712Y | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV64975927; called by muse, mutect2, varscan2
- PHKA1 | c.1487G>A p.G496E | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100263679; called by muse, mutect2, varscan2
- PHKA1 | c.1486G>T p.G496* | Nonsense Mutation (SNP) | VAF 14/92 reads (15%) | catalogued as COSV100263683; called by muse, mutect2, varscan2
- PI16 | c.911C>A p.P304Q | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV65321196; called by muse, mutect2, varscan2
- PIGW | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs763678894; called by muse, mutect2
- PIM1 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.062); catalogued as COSV65166332; called by muse, varscan2
- PKHD1 | c.4617G>T p.Q1539H | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs1401177165, COSV61889050; called by muse, mutect2, varscan2
- PKN3 | c.651+1G>T p.X217_splice | Splice Site (SNP) | VAF 21/68 reads (31%) | catalogued as COSV52578626; called by muse, mutect2, varscan2
- PLCXD3 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as COSV60614452; called by muse, mutect2, varscan2
- PLD1 | c.1093G>T p.V365L | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV60572079; called by muse, mutect2, varscan2
- PLD3 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.262); catalogued as rs767787539, COSV62925527; called by muse, mutect2, varscan2
- PLEKHA6 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55338191; called by muse, mutect2, varscan2
- PLOD1 | c.1268G>T p.S423I | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV52148588; called by muse, mutect2, varscan2
- PLXDC2 | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 12/147 reads (8%) | catalogued as COSV65907096; called by muse, mutect2
- POTEE | c.2422G>C p.A808P | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.715); catalogued as COSV58239062; called by muse, mutect2, varscan2
- PPFIA4 | c.2054G>T p.R685L (on ENST00000447715; = p.R686L on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as COSV55314881, COSV55319441; called by muse, mutect2, varscan2
- PRDM14 | c.537G>T p.E179D | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV52574574; called by muse, mutect2, varscan2
- PREX2 | c.3245G>A p.S1082N | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.039); catalogued as rs774652439, COSV55790767; called by muse, mutect2, varscan2
- PRKN | c.1330del p.E444Sfs*197 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as COSV100628057, COSV58254631; called by mutect2, pindel
- PRRC2C | c.4234G>T p.E1412* (on ENST00000367742; = p.E1410* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV58910396; called by muse, mutect2, varscan2
- PSME4 | c.2901G>A p.M967I | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66366747; called by muse, mutect2, varscan2
- PTBP1 | c.1568G>C p.R523P (on ENST00000349038 / NM_031991.4; = p.R549P on NM_002819.5) | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62461271, COSV62462166; called by muse, mutect2, varscan2
- PTCH2 | c.1666C>T p.R556W | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763426183, COSV64710639; called by muse, mutect2, varscan2
- PTCHD4 | c.2431C>A p.P811T | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as COSV59792405; called by muse, mutect2, varscan2
- PTGER3 | c.1129C>A p.Q377K | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs143165473, COSV63039752; called by muse, mutect2, varscan2
- PTPRD | c.3952C>A p.P1318T | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV61957335, COSV61971137; called by muse, mutect2, varscan2
- PXDNL | c.3805G>T p.A1269S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.038); catalogued as COSV100685291; called by muse, mutect2, varscan2
- PXK | c.1108G>T p.V370L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.182); catalogued as COSV57086260, COSV57091753; called by muse, mutect2, varscan2
- PYGB | c.244-1G>T p.X82_splice | Splice Site (SNP) | VAF 13/71 reads (18%) | catalogued as COSV99405363; called by muse, mutect2, varscan2
- QSER1 | c.199T>A p.F67I (on ENST00000399302; = p.F196I on NM_001076786.3) | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV67901364; called by muse, mutect2, varscan2
- QSOX2 | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.905); catalogued as COSV62394307, COSV62394889; called by muse, mutect2, varscan2
- R3HDM1 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.997); catalogued as COSV51529380, COSV51529799; called by muse, mutect2, varscan2
- RAD54L2 | c.3071G>T p.R1024L | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV56580608; called by muse, mutect2, varscan2
- RADX | c.2173C>T p.Q725* | Nonsense Mutation (SNP) | VAF 21/100 reads (21%) | catalogued as COSV65319661; called by muse, mutect2, varscan2
- RB1CC1 | c.898G>C p.D300H | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs767469821, COSV50263481, COSV99212493; called by muse, mutect2, varscan2
- RBM41 | c.682G>C p.G228R | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.091); catalogued as COSV52564603; called by muse, mutect2, varscan2
- RBM6 | c.1545G>A p.M515I | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV56486184; called by muse, mutect2, varscan2
- RBM6 | c.3241G>T p.E1081* | Nonsense Mutation (SNP) | VAF 8/90 reads (9%) | catalogued as COSV56482578, COSV56486198; called by muse, mutect2
- RBMXL1 | c.950G>C p.R317P | Missense Mutation (SNP) | VAF 63/330 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV53099432, COSV53104180; called by muse, mutect2, varscan2
- RGS8 | c.437C>A p.A146D (on ENST00000367556 / NM_001369564.2; = p.A164D on NM_033345.3) | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51118401; called by muse, varscan2
- RNF38 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV52396623; called by muse, mutect2, varscan2
- ROS1 | c.6196G>T p.G2066C | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63859377; called by muse, mutect2, varscan2
- RP1 | c.846A>T p.K282N | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV55123062; called by muse, mutect2, varscan2
- RRM2B | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.316); catalogued as COSV52568060; called by muse, mutect2, varscan2
- RTP1 | c.530T>A p.V177E | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as COSV56619156; called by muse, mutect2, varscan2
- RYR2 | c.14676del p.I4893* | Frame Shift Del (DEL) | VAF 25/139 reads (18%) | catalogued as COSV63721966, COSV63722189; called by mutect2, pindel, varscan2
- SAMD13 | c.305T>C p.L102P (on ENST00000370671; = p.L96P on NM_001010971.3) | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101043089; called by muse, mutect2, varscan2
- SCAF4 | c.3397G>T p.V1133F | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as COSV54256868; called by muse, mutect2, varscan2
- SCRN3 | c.19G>T p.D7Y | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55809173; called by muse, mutect2, varscan2
- SERBP1 | c.787G>A p.E263K (on ENST00000370995 / NM_001018067.2; = p.E242K on NM_015640.4) | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as COSV63414030; called by muse, mutect2, varscan2
- SERPINE1 | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV56169873; called by muse, mutect2, varscan2
- SETBP1 | c.2566G>A p.V856M | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV56331534; called by muse, mutect2, varscan2
- SHOC2 | c.754C>T p.H252Y | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.939); catalogued as COSV54623570; called by muse, mutect2
- SI | c.1695C>G p.S565R | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52292093; called by muse, mutect2, varscan2
- SLC10A2 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55360805; called by muse, mutect2, varscan2
- SLC17A4 | c.1205C>T p.S402F | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as COSV64956923; called by muse, mutect2, varscan2
- SLC17A4 | c.1482C>A p.F494L | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55081006; called by muse, mutect2, varscan2
- SLC17A8 | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV60125615; called by muse, mutect2, varscan2
- SLC26A5 | c.512G>C p.R171T | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1216316708, COSV59701945, COSV59704629; called by muse, mutect2, varscan2
- SLC39A12 | c.901G>T p.D301Y | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as COSV66201251; called by muse, mutect2, varscan2
- SLC4A7 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV55400890; called by muse, mutect2, varscan2
- SLC6A15 | c.523C>A p.Q175K | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as COSV57027260; called by mutect2, varscan2
- SLC9A4 | c.448C>G p.P150A | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV54837321; called by muse, mutect2, varscan2
- SLC9A9 | c.1567G>T p.A523S | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.163); catalogued as COSV57220612; called by muse, mutect2, varscan2
- SLC9A9 | c.994C>A p.L332I | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV57238752; called by muse, mutect2, varscan2
- SLCO4A1 | c.2032G>T p.G678C | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV53892828; called by muse, mutect2, varscan2
- SLIT2 | c.1437A>T p.S479= | Splice Region (SNP) | VAF 24/115 reads (21%) | catalogued as COSV56586791; called by muse, mutect2, varscan2
- SLIT3 | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100269030, COSV60614576; called by muse, mutect2
- SLITRK3 | c.2668C>A p.P890T | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs550891799, COSV53851582; called by muse, mutect2, varscan2
- SNTG1 | c.1344del p.S448Rfs*40 | Frame Shift Del (DEL) | VAF 24/116 reads (21%) | catalogued as COSV52428190; called by mutect2, pindel, varscan2
- SORCS1 | c.2395G>A p.G799R | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1427827528, COSV53891284; called by muse, mutect2, varscan2
- SORCS3 | c.795+1G>A p.X265_splice | Splice Site (SNP) | VAF 9/60 reads (15%) | catalogued as COSV63819339; called by muse, mutect2, varscan2
- SP110 | c.1531G>T p.A511S | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV51247407, COSV51266921; called by muse, mutect2, varscan2
- SP8 | c.10G>T p.A4S (on ENST00000361443 / NM_198956.4; = p.A22S on NM_182700.6) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63866710; called by muse, mutect2, varscan2
- SPATA31D1 | c.2298G>A p.M766I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV61199198; called by muse, mutect2, varscan2
- SPEG | c.2140G>C p.A714P | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100403249, COSV100404057, COSV56676473; called by muse, mutect2
- SPEG | c.3011G>T p.R1004L | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); catalogued as COSV56665005; called by muse, mutect2, varscan2
- SRCAP | c.7695G>T p.E2565D | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.935); catalogued as COSV52678179; called by muse, mutect2, varscan2
- SRPK3 | c.1004C>A p.S335Y | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as rs782457009, COSV54209277, COSV99473159; called by muse, mutect2, varscan2
- SRRM2 | c.2972G>T p.G991V | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as COSV57078556; called by muse, mutect2, varscan2
- SRSF7 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.885); catalogued as rs375213460; called by muse, mutect2, varscan2
- STAB2 | c.1919C>A p.A640D | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV66343991; called by muse, mutect2, varscan2
- STAB2 | c.3379C>A p.L1127M | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66343997; called by muse, mutect2
- STAG1 | c.1986T>G p.I662M | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV52618924; called by muse, mutect2, varscan2
- STX11 | c.827G>T p.R276L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.389); catalogued as rs762359713, COSV62448496, COSV62449930; called by muse, mutect2, varscan2
- STX1B | c.157G>T p.V53L | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.156); catalogued as COSV53061803; called by muse, mutect2, varscan2
- SUGP2 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.503); catalogued as COSV58262820; called by muse, mutect2
- SULF1 | c.1903T>C p.S635P | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52688863; called by muse, mutect2, varscan2
- SULT1C2 | c.18C>A p.D6E | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV52266264; called by muse, mutect2, varscan2
- SUN3 | c.1051G>T p.G351C | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52052659; called by muse, mutect2, varscan2
- SV2C | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV59225785; called by muse, mutect2, varscan2
- SYNE3 | c.813G>T p.R271S | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV62081379; called by muse, mutect2
- SYT1 | c.179C>A p.A60D | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV99696710; called by muse, mutect2, varscan2
- TAL1 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53747979; called by muse, mutect2
- TAS2R60 | c.736C>G p.L246V | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV60331658; called by muse, mutect2, varscan2
- TCEANC | c.256G>T p.A86S (on ENST00000380600 / NM_001297563.2; = p.A116S on NM_152634.4) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100124798; called by muse, mutect2, varscan2
- TECPR2 | c.691C>G p.L231V | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV63972758; called by muse, mutect2, varscan2
- TEP1 | c.4647+1G>T p.X1549_splice | Splice Site (SNP) | VAF 56/220 reads (25%) | catalogued as COSV52997112, COSV99403654; called by muse, mutect2, varscan2
- TFAP2D | c.850G>C p.A284P | Missense Mutation (SNP) | VAF 7/178 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50439902, COSV99147078; called by muse, mutect2
- TGM1 | c.1951G>T p.A651S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV52864593; called by muse, mutect2, varscan2
- THRAP3 | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 65/330 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as COSV63566888, COSV63569175, COSV63569952; called by muse, mutect2, varscan2
- TIAM1 | c.3547G>A p.E1183K | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54565803; called by muse, mutect2, varscan2
- TLL2 | c.2867G>T p.G956V | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63574569; called by muse, mutect2, varscan2
- TLR1 | c.1636G>T p.V546L | Missense Mutation (SNP) | VAF 63/380 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.028); catalogued as COSV58305186; called by muse, mutect2, varscan2
- TMED1 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 13/125 reads (10%) | catalogued as COSV99284240; called by muse, mutect2, varscan2
- TMEM236 | c.979G>T p.V327L | Missense Mutation (SNP) | VAF 27/205 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs1036475545; called by muse, mutect2, varscan2
- TP63 | c.1971G>T p.E657D | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV53215670; called by muse, mutect2, varscan2
- TRANK1 | c.2803A>G p.K935E | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as COSV57159579; called by muse, mutect2, varscan2
- TREML1 | c.479+1G>T p.X160_splice | Splice Site (SNP) | VAF 10/76 reads (13%) | catalogued as COSV100914316, COSV104427083; called by muse, mutect2
- TRIM52 | c.116_118del p.F39del | In Frame Del (DEL) | VAF 5/37 reads (14%) | catalogued as rs1561691978; called by mutect2, pindel, varscan2
- TRPV3 | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV56793785; called by muse, mutect2, varscan2
- TSEN34 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV55477080; called by muse, mutect2
- TTC17 | c.2581G>C p.E861Q | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV50014714; called by muse, mutect2, varscan2
- TTN | c.24025G>T p.V8009L (on ENST00000591111; = p.V7082L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/145 reads (14%) | PolyPhen benign (0.017); catalogued as COSV60239428; called by muse, mutect2, varscan2
- TUBA1A | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as COSV55498567; called by muse, mutect2, varscan2
- TUT4 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as COSV57117928; called by muse, mutect2, varscan2
- UBE4B | c.3262G>T p.A1088S (on ENST00000343090 / NM_001105562.3; = p.A959S on NM_006048.5) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); catalogued as rs1181189771, COSV53538435; called by muse, mutect2, varscan2
- UBR1 | c.371G>C p.C124S | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51934122; called by muse, mutect2
- UBR3 | c.4069G>T p.E1357* | Nonsense Mutation (SNP) | VAF 25/80 reads (31%) | catalogued as COSV55856456; called by muse, mutect2, varscan2
- UGT1A4 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 49/254 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.9); catalogued as rs372293131; called by muse, mutect2, varscan2
- UGT2B17 | c.332C>G p.S111* | Nonsense Mutation (SNP) | VAF 34/78 reads (44%) | catalogued as COSV100497273; called by muse, mutect2, varscan2
- UMOD | c.858C>A p.Y286* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as rs1334973619, COSV56778214; called by muse, mutect2, varscan2
- UNC79 | c.5530G>T p.A1844S (on ENST00000393151 / NM_001346218.2; = p.A1667S on NM_020818.5) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); catalogued as COSV56402405; called by muse, mutect2, varscan2
- UNC79 | c.7223G>T p.C2408F (on ENST00000393151 / NM_001346218.2; = p.C2231F on NM_020818.5) | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56402425; called by muse, mutect2, varscan2
- USH2A | c.9945C>A p.Y3315* | Nonsense Mutation (SNP) | VAF 15/92 reads (16%) | catalogued as rs1161652737, COSV56367389; called by muse, mutect2, varscan2
- USH2A | c.1687C>A p.Q563K | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as COSV56410311; called by muse, mutect2, varscan2
- USP46 | c.850A>G p.N284D | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV71513095; called by muse, mutect2, varscan2
- USP7 | c.1523G>T p.R508L | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV61215245, COSV61216508; called by muse, mutect2, varscan2
- VARS1 | c.2013G>T p.E671D | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100791838; called by muse, mutect2, varscan2
- VCAN | c.5543C>G p.T1848S | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as rs1445154009, COSV54112710; called by muse, mutect2, varscan2
- VPS13C | c.10627G>C p.A3543P (on ENST00000644861 / NM_020821.3; = p.A3500P on NM_017684.5) | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51363003; called by muse, mutect2, varscan2
- VWA3A | c.1800C>G p.D600E | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.615); catalogued as COSV55393859; called by muse, mutect2, varscan2
- WDR64 | c.1148G>T p.S383I | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63798739; called by muse, mutect2, varscan2
- WDR7 | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV54355623, COSV54359893; called by muse, mutect2, varscan2
- WDR86 | c.375C>A p.D125E | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV57842488; called by muse, mutect2, varscan2
- WNT1 | c.195C>A p.S65R | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.589); catalogued as COSV53296566, COSV99525220; called by muse, mutect2, varscan2
- WTAP | c.1058C>G p.S353* | Nonsense Mutation (SNP) | VAF 13/114 reads (11%) | catalogued as COSV64330554; called by muse, mutect2, varscan2
- XIRP2 | c.210G>T p.M70I | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV54684366; called by muse, mutect2, varscan2
- YIPF1 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50778741; called by muse, mutect2, varscan2
- ZFYVE28 | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 6/55 reads (11%) | catalogued as COSV52115205; called by muse, mutect2, varscan2
- ZNF334 | c.1777A>G p.T593A | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.133); catalogued as COSV61619660; called by muse, mutect2, varscan2
- ZNF385D | c.164C>A p.A55E | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV55753651, COSV55768121; called by muse, mutect2, varscan2
- ZNF408 | c.2087C>A p.P696H | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV61238931; called by muse, mutect2, varscan2
- ZNF430 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 35/135 reads (26%) | catalogued as COSV55111705; called by muse, mutect2, varscan2
- ZNF536 | c.2441G>T p.G814V | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV62826344, COSV62830641; called by muse, mutect2, varscan2
- ZNF567 | c.1648G>T p.V550L (on ENST00000536254 / NM_001322913.1; = p.V519L on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.082); catalogued as COSV62446159; called by muse, mutect2, varscan2
- ZNF598 | c.2257T>A p.F753I | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50192433; called by muse, mutect2
- ZNF697 | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV70284256; called by muse, mutect2, varscan2
- ZNF791 | c.1709A>G p.H570R | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58482138; called by muse, mutect2, varscan2
- ZNF98 | c.1520C>A p.T507K | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63338558; called by muse, mutect2, varscan2
- ZSWIM2 | c.1753A>G p.T585A | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs1350302843, COSV54577907; called by muse, mutect2
- ZWILCH | c.1711G>T p.G571C | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.271); catalogued as COSV57181979; called by muse, mutect2, varscan2
- ADAL | c.460_461del p.L154Sfs*17 | Frame Shift Del (DEL) | VAF 8/96 reads (8%) | called by mutect2, pindel
- BMP7 | c.640del p.R214Vfs*51 | Frame Shift Del (DEL) | VAF 12/65 reads (18%) | called by mutect2, pindel, varscan2
- C16orf82 | c.258C>G p.S86R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- IGLV5-48 | c.123C>A p.C41* | Nonsense Mutation (SNP) | VAF 72/310 reads (23%) | called by muse, varscan2
- LTBP4 | c.3236G>T p.G1079V (on ENST00000308370 / NM_001042544.1; = p.G1042V on NM_003573.2) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OPRM1 | c.324del p.Y108* | Frame Shift Del (DEL) | VAF 24/113 reads (21%) | called by mutect2, pindel, varscan2
- OR8G2P | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); called by muse, varscan2
- PAPPA | c.888dup p.W297Lfs*37 | Frame Shift Ins (INS) | VAF 13/51 reads (25%) | called by mutect2, pindel, varscan2
- PHGDH | c.824dup p.H275Qfs*2 | Frame Shift Ins (INS) | VAF 11/55 reads (20%) | called by mutect2, pindel, varscan2
- PKP1 | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2
- POSTN | c.981dup p.T328Yfs*3 | Frame Shift Ins (INS) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- PPIAL4A | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.274); called by muse, varscan2
- TRHDE | c.2355dup p.A786Cfs*13 | Frame Shift Ins (INS) | VAF 12/65 reads (18%) | called by mutect2, pindel, varscan2
- TRPA1 | c.1409del p.S470Mfs*6 | Frame Shift Del (DEL) | VAF 13/76 reads (17%) | called by mutect2, pindel, varscan2
- XIRP2 | c.4604del p.G1535Vfs*41 (on ENST00000628543; = p.G1710Vfs*41 on NM_152381.6) | Frame Shift Del (DEL) | VAF 16/80 reads (20%) | called by mutect2, pindel*, varscan2
- ZBED9 | c.2585dup p.K863Efs*10 | Frame Shift Ins (INS) | VAF 19/182 reads (10%) | called by mutect2, pindel, varscan2
- ABCA12 | c.6771T>C p.Y2257= (on ENST00000272895 / NM_173076.3; = p.Y1939= on NM_015657.3) | Silent (SNP) | VAF 40/146 reads (27%) | catalogued as COSV55969698; called by muse, mutect2, varscan2
- ABCC2 | c.3477C>A p.I1159= | Silent (SNP) | VAF 8/97 reads (8%) | catalogued as COSV64987839; called by muse, mutect2
- ACBD6 | c.831C>T p.H277= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV62575277; called by muse, mutect2, varscan2
- ADAMTS12 | c.1236G>T p.V412= | Silent (SNP) | VAF 8/158 reads (5%) | catalogued as COSV61272780; called by muse, mutect2
- ADCY1 | c.813G>T p.L271= | Silent (SNP) | VAF 24/132 reads (18%) | catalogued as rs750321646, COSV52039625; called by muse, mutect2, varscan2
- ADCY5 | c.1635C>A p.I545= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV59201705; called by muse, mutect2, varscan2
- AKAP6 | c.834T>A p.A278= | Silent (SNP) | VAF 31/123 reads (25%) | catalogued as COSV55225869; called by muse, mutect2, varscan2
- AMER3 | c.1218C>A p.G406= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV58468841; called by muse, mutect2, varscan2
- ARHGAP32 | c.5358G>T p.G1786= (on ENST00000310343 / NM_001378025.1; = p.G1437= on NM_014715.4) | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as COSV59853052; called by muse, mutect2, varscan2
- ARHGAP36 | c.636C>T p.S212= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV52270164; called by muse, mutect2, varscan2
- ARSH | c.306G>C p.L102= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as COSV66963620; called by muse, mutect2, varscan2
- ASGR1 | c.843G>C p.L281= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV52649392; called by muse, mutect2, varscan2
- BMP2K | c.3021T>A p.T1007= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV55011165; called by muse, mutect2, varscan2
- C9orf72 | c.648T>C p.H216= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs149801256; called by muse, mutect2, varscan2
- CACNA1C | c.4131C>A p.I1377= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV59754002, COSV59754317; called by mutect2, varscan2
- CASQ2 | c.657A>G p.P219= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV54772793; called by muse, mutect2, varscan2
- CD44 | c.1131G>A p.E377= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV53530697; called by muse, mutect2, varscan2
- CHRNA4 | c.1011G>T p.T337= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV100937459, COSV64718567; called by muse, mutect2, varscan2
- CLVS2 | c.429T>C p.S143= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as COSV51567113; called by muse, mutect2, varscan2
- COBL | c.3138C>T p.H1046= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs768602767, COSV54346020; called by muse, mutect2, varscan2
- COL9A1 | c.48C>T p.F16= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs1471926706, COSV61830730; called by muse, mutect2
- COPS7A | c.684C>T p.A228= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs199950835, COSV57527355; called by muse, mutect2, varscan2
- CR2 | c.2043T>C p.V681= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV65508940; called by muse, mutect2, varscan2
- CREB5 | c.1152G>A p.R384= (on ENST00000357727 / NM_182898.4; = p.R377= on NM_004904.3) | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV63226196; called by muse, mutect2, varscan2
- CST6 | c.441G>T p.V147= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as rs202231090, COSV56412597; called by muse, mutect2, varscan2
- CTBP1 | c.1089C>T p.A363= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV52075660; called by muse, mutect2, varscan2
- CTSH | c.147G>A p.E49= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs780053060, COSV54986035; called by muse, mutect2, varscan2
- CYP19A1 | c.561G>C p.V187= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV53061354; called by muse, mutect2, varscan2
- CYP26B1 | c.528C>G p.P176= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV50013503; called by muse, mutect2, varscan2
- CYP2W1 | c.1035C>A p.P345= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV58270680; called by muse, mutect2, varscan2
- DCAF12L2 | c.661C>A p.R221= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100758442, COSV63583588; called by muse, mutect2, varscan2
- DDI1 | c.819C>A p.A273= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV56388022; called by muse, mutect2, varscan2
- DPY19L1 | c.2010A>T p.L670= | Silent (SNP) | VAF 27/136 reads (20%) | catalogued as rs748132209, COSV60583508; called by muse, mutect2, varscan2
- DRD5 | c.504C>A p.S168= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV58579589; called by muse, mutect2
- ERCC1 | c.339G>A p.L113= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV50005002; called by muse, mutect2, varscan2
- FAM151A | c.865C>A p.R289= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as COSV56365371; called by muse, mutect2, varscan2
- FAM171A1 | c.2118G>T p.R706= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as COSV65318506; called by muse, mutect2, varscan2
- FAT2 | c.8799T>A p.A2933= | Silent (SNP) | VAF 43/178 reads (24%) | catalogued as COSV55826133; called by muse, mutect2, varscan2
- FAT3 | c.4920C>T p.S1640= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV53153069; called by muse, mutect2, varscan2
- FBXO40 | c.789T>C p.A263= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV57526291; called by muse, varscan2
- FCRL3 | c.1287C>A p.A429= | Silent (SNP) | VAF 28/173 reads (16%) | catalogued as COSV63843792; called by muse, mutect2, varscan2
- GBP4 | c.736C>A p.R246= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as COSV63255473; called by muse, mutect2, varscan2
- GPR26 | c.549C>A p.L183= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV52935586; called by muse, mutect2, varscan2
- GRM5 | c.147G>C p.V49= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV100551647, COSV59619232; called by muse, mutect2, varscan2
- GTPBP2 | c.1723C>A p.R575= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as rs764127861, COSV100200065, COSV61077515; called by muse, mutect2, varscan2
- HACE1 | c.2478G>A p.E826= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as COSV53505583; called by muse, mutect2, varscan2
- HDAC9 | c.234G>A p.Q78= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs1391233445, COSV67781271; called by muse, mutect2, varscan2
- HOXC10 | c.603C>A p.T201= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV100329129; called by muse, mutect2, varscan2
- HSPA13 | c.1278C>T p.P426= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV53466019; called by muse, mutect2, varscan2
- IER5 | c.336G>T p.R112= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV62537186; called by muse, mutect2, varscan2
- IGFL3 | c.252C>A p.P84= | Silent (SNP) | VAF 71/187 reads (38%) | catalogued as COSV58243173; called by muse, mutect2, varscan2
- IGKV1-17 | c.138G>T p.R46= | Silent (SNP) | VAF 51/263 reads (19%) | called by muse, mutect2, varscan2
- INCENP | c.762G>T p.A254= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV53914918, COSV53919233; called by muse, mutect2, varscan2
- ITGA6 | c.2145A>T p.I715= (on ENST00000442250; = p.I676= on NM_000210.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV51242294; called by muse, mutect2, varscan2
- ITIH6 | c.2289G>A p.V763= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV54492492; called by muse, mutect2
- IZUMO2 | c.207G>T p.A69= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV53229960, COSV53230953; called by muse, mutect2, varscan2
- KCND2 | c.1722C>A p.S574= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV100478190, COSV58595606; called by muse, mutect2
- KRT73 | c.855G>C p.T285= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as COSV59841010; called by muse, mutect2, varscan2
- KRT77 | c.573G>T p.V191= | Silent (SNP) | VAF 25/155 reads (16%) | catalogued as COSV59240873; called by muse, mutect2, varscan2
- LGR5 | c.1791G>T p.G597= | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as COSV57008207; called by muse, mutect2, varscan2
- LMOD2 | c.1131C>A p.T377= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as COSV71755774; called by muse, mutect2, varscan2
- MAGEA12 | c.741C>G p.T247= | Silent (SNP) | VAF 49/211 reads (23%) | catalogued as COSV100756996; called by muse, mutect2, varscan2
- MAGEB6 | c.735G>A p.V245= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV66872732; called by muse, mutect2, varscan2
- MAT1A | c.678C>A p.V226= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV64746620; called by muse, mutect2, varscan2
- MCEMP1 | c.177G>T p.T59= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV58040011, COSV58040669; called by muse, mutect2, varscan2
- MRAP2 | c.24T>A p.S8= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as COSV100004927; called by muse, mutect2, varscan2
- MROH2B | c.2103C>A p.V701= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as COSV68187084, COSV68187523; called by muse, mutect2
- MROH2B | c.1092T>A p.G364= | Silent (SNP) | VAF 26/193 reads (13%) | catalogued as COSV68187528; called by muse, mutect2, varscan2
- NCKAP5 | c.5298C>A p.A1766= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV58463956; called by muse, mutect2
- NKAIN4 | c.591C>A p.S197= | Silent (SNP) | VAF 39/250 reads (16%) | catalogued as COSV53902649; called by muse, mutect2, varscan2
- NLRP3 | c.1116C>A p.S372= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV60229244; called by muse, mutect2, varscan2
- NOS1 | c.3729G>T p.R1243= | Silent (SNP) | VAF 21/134 reads (16%) | catalogued as COSV100501120; called by muse, mutect2, varscan2
- NPTX2 | c.864C>A p.P288= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV55718458; called by muse, mutect2, varscan2
- NTNG1 | c.315G>T p.L105= | Silent (SNP) | VAF 51/256 reads (20%) | catalogued as COSV53982316; called by muse, mutect2, varscan2
- OR11G2 | c.225G>T p.L75= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV62132849; called by muse, mutect2, varscan2
- OR52K2 | c.465G>T p.V155= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as COSV57835600; called by muse, mutect2, varscan2
- OR6N2 | c.781C>A p.R261= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV59410585, COSV59412494; called by muse, mutect2, varscan2
- OSM | c.495C>A p.P165= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99304273; called by muse, mutect2
- PCDH7 | c.2964C>A p.G988= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs148242685, COSV100687712; called by muse, mutect2, varscan2
- PCDHGB4 | c.2157C>T p.P719= | Silent (SNP) | VAF 46/206 reads (22%) | catalogued as COSV54001514; called by muse, mutect2, varscan2
- PODN | c.1584G>C p.L528= (on ENST00000395871; = p.L480= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV57015986; called by muse, mutect2
- PORCN | c.180G>A p.G60= | Silent (SNP) | VAF 18/123 reads (15%) | catalogued as COSV58226908; called by muse, mutect2, varscan2
- PRAME | c.1119G>A p.L373= | Silent (SNP) | VAF 46/123 reads (37%) | catalogued as COSV67162252; called by muse, mutect2, varscan2
- PTCHD4 | c.1515C>A p.A505= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV59792417; called by muse, mutect2, varscan2
- PTPRT | c.465T>A p.T155= | Silent (SNP) | VAF 7/173 reads (4%) | catalogued as COSV62005306; called by muse, mutect2
- QRICH2 | c.51G>T p.R17= | Silent (SNP) | VAF 48/166 reads (29%) | catalogued as COSV53156384; called by muse, mutect2, varscan2
- RASGRF1 | c.2595C>G p.P865= | Silent (SNP) | VAF 26/160 reads (16%) | catalogued as COSV101174565, COSV67250831; called by muse, mutect2, varscan2
- RLBP1 | c.18C>A p.G6= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV51528971; called by muse, mutect2, varscan2
- RYR2 | c.11382C>T p.A3794= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as rs760519786, COSV63703556; ClinVar: likely benign; called by muse, mutect2, varscan2
- SDK2 | c.1833G>C p.T611= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs146912233, COSV66191429, COSV66192854; called by muse, mutect2
- SEMA4D | c.1722G>C p.L574= | Silent (SNP) | VAF 23/221 reads (10%) | catalogued as COSV59398922; called by muse, mutect2
- SEMA6D | c.336C>A p.G112= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV60381617; called by muse, mutect2, varscan2
- SH3TC2 | c.1227G>A p.E409= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV60466236; called by muse, mutect2, varscan2
- SLC1A3 | c.744C>A p.V248= | Silent (SNP) | VAF 77/137 reads (56%) | catalogued as COSV54318863; called by muse, mutect2, varscan2
- SLFN12 | c.1323C>T p.L441= | Silent (SNP) | VAF 38/103 reads (37%) | catalogued as COSV59227093; called by muse, mutect2, varscan2
- SPTBN1 | c.4296G>T p.R1432= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV100442678, COSV61691768; called by muse, mutect2, varscan2
- STK10 | c.1212G>T p.L404= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV99452033; called by muse, mutect2, varscan2
- TAS2R10 | c.771G>T p.L257= | Silent (SNP) | VAF 15/122 reads (12%) | catalogued as COSV53701461; called by muse, mutect2, varscan2
- TINF2 | c.1090C>T p.L364= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as rs1418269939, COSV57469824; called by muse, mutect2
- TMED3 | c.568C>T p.L190= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV55303274; called by muse, mutect2, varscan2
- TMEM63B | c.2244A>T p.T748= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV52481490; called by muse, mutect2, varscan2
- UBR4 | c.405C>T p.G135= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV64386311; called by muse, mutect2, varscan2
- UTP25 | c.186A>G p.S62= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as rs748384339, COSV72227447, COSV72227482; called by muse, mutect2
- WNK3 | c.3610C>T p.L1204= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV63615298; called by muse, mutect2, varscan2
- XIRP2 | c.3576T>A p.T1192= (on ENST00000628543; = p.T1367= on NM_152381.6) | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV54687142; called by muse, mutect2, varscan2
- ZFHX4 | c.6636C>T p.P2212= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV50678981; called by muse, mutect2, varscan2
- ZNF205 | c.1554C>T p.N518= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV54622304; called by muse, mutect2
- ZNF208 | c.3756C>A p.P1252= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV68110627; called by muse, varscan2
- ZNF699 | c.345A>G p.E115= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV58026550; called by muse, mutect2, varscan2
- ZNF711 | c.276G>T p.A92= | Silent (SNP) | VAF 49/185 reads (26%) | catalogued as rs745920796, COSV52157267; called by muse, mutect2, varscan2
- ZNF766 | c.750G>A p.K250= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV63010014; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824585 del G | 5'Flank (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- ATP6V0E1 | chr5:173020781 G>C | 3'Flank (SNP) | VAF 19/80 reads (24%) | catalogued as COSV99439248; called by muse, mutect2, varscan2
- CACNA1C | c.3829-658G>T | Intron (SNP) | VAF 9/78 reads (12%) | catalogued as COSV59721044; called by muse, mutect2, varscan2
- COL11A1 | c.898-247A>T | Intron (SNP) | VAF 24/163 reads (15%) | catalogued as COSV100617722; called by muse, mutect2, varscan2
- CPED1 | c.*1G>T | 3'UTR (SNP) | VAF 21/82 reads (26%) | catalogued as COSV100121238; called by muse, varscan2
- ESPN | chr1:6460117 ins T | 3'Flank (INS) | VAF 11/57 reads (19%) | called by mutect2, pindel, varscan2
- H2BP2 | n.1062-279A>G | Intron (SNP) | VAF 31/152 reads (20%) | called by muse, mutect2, varscan2
- PRR12 | c.52-497G>A | Intron (SNP) | VAF 4/18 reads (22%) | catalogued as rs1202941397, COSV69819314; called by muse, mutect2, varscan2
- SNORD116-23 | n.22C>A | RNA (SNP) | VAF 29/216 reads (13%) | called by muse, mutect2, varscan2
- TTLL11 | c.1539+44G>T | Intron (SNP) | VAF 26/83 reads (31%) | catalogued as COSV58650472; called by muse, mutect2, varscan2
- VNN3 | c.*190dup | 3'UTR (INS) | VAF 13/85 reads (15%) | called by mutect2, pindel, varscan2
- XIRP2 | c.*277T>A | 3'UTR (SNP) | VAF 15/91 reads (16%) | catalogued as COSV99745771; called by muse, mutect2, varscan2
